Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NL-01A (Primary Tumor).

ICDD-3

Carcinoma, hepatocellular NOS
Site: Liver C22.0
8170/3
9/12/24/12

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6

Tissue from liver segment VI with portion of liver segment V (255.0 grams, 11.9 x 8.5 x 8.0 cm).

DIAGNOSIS:

Liver, segment VI with portion of segment V, resection: Well differentiated hepatocellular carcinoma forming a mass (3.6 x 2.1 x 2.1 cm). The surgical resection margins are uninvolved. See comment.

Seen in consultation with

Comment: Reticulin stain shows loss of reticulin framework in the carcinoma.

ICD-9 Discrepancy		✓
Date Review	9/20/12	9/20/12

Source: NCI Genomic Data Commons file fd417968-0aa3-4e3c-ad4f-4fb9f90bc0c5 (TCGA-DD-A4NL.54C7EDE1-EDBE-44A4-A3BE-FD639D6891DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).